Gene-level copy-number profile of tumor specimen TCGA-CM-5862-01A from TCGA case TCGA-CM-5862, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 80.7 years (29,493 days).
Specimen TCGA-CM-5862-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.262b30d5-351c-43de-90ce-eddbc969c164.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CM-5862-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6320e34-d3dc-487b-b321-1e1f53ed2429

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 5,837; copy number 2: 30,589; copy number 3: 16,975; copy number 4: 2,290; copy number 5: 180; copy number 6: 1,399; copy number 7: 1,293; copy number 8: 500; copy number 9: 51; copy number 10: 587; copy number 11: 50; copy number 13: 4; copy number 14: 25; copy number 15: 9; copy number 18: 11; copy number 19: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CM-5862-01A-01D-1649-01): tumor purity 0.86, ploidy 2.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:4,269,153–4,317,567, 2 genes (within-gene range 0–1): AC023483.1, SETMAR.
- chr8:150,584–384,079, 13 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,113 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:27,133,996–27,985,063, 8 genes, copy number 6: AC024132.2, AC024132.1, LINC02261, Y_RNA, AC024132.3, IGBP1P5, AC007106.2, AC007106.1.
- chr7:70,972–68,119,209, 1,283 genes, copy number 6 (broad region; genes not listed).
- chr8:54,509,422–54,871,720, 1 gene, copy number 5 (within-gene range 4–5): RP1.
- chr8:54,696,398–145,066,685, 1,401 genes, copy number 5–7 (broad region; genes not listed).
- chr10:1,957,589–3,556,314, 30 genes, copy number 5: AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1, AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1.
- chr13:18,467,172–114,337,626, 1,390 genes, copy number 7–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,451. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
